Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IX, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IX-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD O-3

Adenocarcinoma duct NOS
8500/3

Site Pancreas head
C25.0

JW 4/16/14

Final Diagnosis

- A. LIVER, NODULE, BIOPSY:
Benign hepatic parenchyma.
- B. HEAD OF PANCREAS, DISTAL STOMACH AND DUODENUM, STANDARD PANCREATODUODENECTOMY:
Adenocarcinoma, moderately differentiated, confined to the pancreas.
Pancreatic neck margin with panIN 1A and 1B.
Adjacent pancreatic parenchyma with panIN 3.
Thirty-five lymph nodes are free of metastases (0/35).
Proximal gastric and distal duodenal margins are free of dysplasia and carcinoma.
Superior mesenteric artery and posterior surface are free of carcinoma.
Common bile duct with surface epithelial erosions and reactive changes, negative for high grade dysplasia and carcinoma
See synoptic report.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by

Key Pathological Findings

B: Pancreas Exocrine

SPECIMEN:

Head of pancreas
Duodenum
Stomach
Common bile duct

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension of solid component: 2.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor is confined to pancreas

MARGINS:

Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 5 mm

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

[page 2 of 3]
Present
TNM DESCRIPTORS:
Not applicable
PRIMARY TUMOR (pT):
pT1: Tumor limited to the pancreas, 2 cm or less in greatest dimension
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
Number examined: 35
Number involved: 0
DISTANT METASTASIS (pM):
Not applicable
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 3)
CLINICAL HISTORY:
Not specified

Specimen(s) Received

A LIVER NODULE FS
B WHIPPLE

Clinical History

PANCREATIC HEAD CANCER

Preoperative Diagnosis

Pancreatic head cancer.

Intraoperative Consultation

FSA1. LIVER NODULE:
Benign.

B. WHIPPLE:
FSB1. Common bile duct; focal mild dysplasia.
FSB2. Pancreas margin; focal PanIN-1, negative for carcinoma.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for frozen section analysis, labeled "liver nodule." The specimen consists of a 1.0 x 0.5 x 0.1 cm, soft, tan-pink irregular fragment of liver, which is entirely submitted for frozen section as FSA1.

B. The specimen is received fresh for frozen section analysis labeled "Whipple; specimen is gallbladder, head of pancreas, distal stomach, and duodenum." The specimen consists of a resected

[page 3 of 3]
portion of head of the pancreas (4.0 x 3.0 x 2.5 cm), the duodenum (12 cm in length and 2 cm in its greatest diameter), distal stomach (3 cm along the lesser curvature and 6.5 cm along the greater curvature), and attached gallbladder (7.0 x 3.0 x 2.5 cm). The landmarks of the specimen are inked as follows; superior mesenteric artery stapled margin of resection yellow, portal vein groove blue, and retroperitoneal surface black.

The pancreatic duct is probed-patent up to about 2 cm, at which point it appears to be obstructed by an ill-defined, indurated pancreatic mass (2.0 x 2.0 x 0.3 cm), grossly coming to within 2 cm of the pancreatic margin of resection, and 0.5 cm of the radial soft tissue margin. Grossly the mass does not appear to involve the common bile duct, ampulla of Vater, or duodenum. The remainder of the pancreatic parenchyma is grossly unremarkable. The gastric and the duodenal mucosa are grossly unremarkable. On opening the attached gallbladder a moderate amount of red-brown, viscous bile is expelled. No calculi are grossly appreciated. The wall of the gallbladder measures up to 3 mm in thickness. The internal surface is red-brown and velvet-like. Dissection of the attached adipose tissue isolates no definitive lymph nodes. The adipose tissue is submitted in its entirety.

Two representative frozen sections are taken and submitted as FSB1 and FSB2. A representative section of the tumor is submitted to the Tissue Procurement Laboratory. Permanent representative sections are submitted as:

- B3: Mirror image of tumor submitted to Tissue Bank.
- B4-B5: Tangential superior mesenteric artery margin of resection.
- B6-B7: Perpendicular pulmonary vein groove.
- B8-B9: Retroperitoneal surface.
- B10-B11: Tangential gastric margin of resection.
- B12: Tangential duodenal margin of resection.
- B13: Tumor showing its relationship to pancreatic duct.
- B14: Tumor showing its relationship to duodenum.
- B15-B16: Tumor showing its relationship to duodenum, common bile duct, and ampulla of Vater.
- B17: Additional section of tumor.
- B18: Tumor showing its relationship to nearest radial margin of resection.
- B19: Grossly unremarkable gastric mucosa.
- B20: Grossly unremarkable duodenum.
- B21: Gallbladder.
- B22-B24: Entire adipose tissue with attached pancreas.
- B25-B30: Entire adipose tissue attached at lesser curvature.
- B31-B54: Entire adipose tissue attached to lesser curvature.

Source: NCI Genomic Data Commons file 498046f8-af59-4a38-8409-b119cd18be2e (TCGA-3A-A9IX.4B708CCE-6C54-4A4B-8E27-519461D5A1C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).